Somatic mutation profile of tumor specimen TCGA-D1-A16B-01A (aliquot TCGA-D1-A16B-01A-11D-A12J-09) from TCGA case TCGA-D1-A16B, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G2; Age at diagnosis: 64.2 years (23,450 days).
Specimen TCGA-D1-A16B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50500f67-60a4-4e8b-8e45-ed99100ae96a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16B-10A (Blood Derived Normal), aliquot TCGA-D1-A16B-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99c6e14c-dbc1-4554-8d86-c6194ed4bbeb

The open-access MAF lists 58 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 11, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 30/102 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 40/140 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 59/198 reads (30%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- AGAP2 | c.2987C>T p.T996I (on ENST00000547588 / NM_001122772.2; = p.T640I on NM_014770.4) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as rs1162962655, COSV57730511; called by muse, mutect2, varscan2
- ARG1 | c.465+1G>T p.X155_splice | Splice Site (SNP) | VAF 30/87 reads (34%) | catalogued as COSV51581531; called by muse, mutect2, varscan2
- BBX | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV57890814; called by muse, mutect2, varscan2
- CADM1 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 81/534 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59010320; called by muse, mutect2, varscan2
- CAMTA1 | c.3274G>A p.A1092T | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.293); catalogued as rs201621529, COSV57917326; called by muse, mutect2, varscan2
- CD200 | c.848A>C p.Y283S (on ENST00000473539 / NM_001004196.3; = p.Y258S on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/344 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV59864103; called by muse, mutect2
- CD300LF | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as rs201675456; called by muse, mutect2
- CYP4F22 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs142720535; called by muse, mutect2, varscan2
- DMD | c.7430G>A p.R2477Q | Missense Mutation (SNP) | VAF 89/204 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs764340452, COSV58935156; called by muse, mutect2, varscan2
- ELAVL1 | c.635A>G p.H212R | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV60968011; called by muse, mutect2, varscan2
- EML3 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs760790853, COSV53883935; called by muse, mutect2, varscan2
- FBXO39 | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 58/184 reads (32%) | catalogued as COSV58622632; called by muse, mutect2, varscan2
- FERMT3 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as rs1456223717, COSV54177651; called by muse, mutect2, varscan2
- FMR1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 168/518 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV54426193; called by muse, varscan2
- GLI3 | c.3783G>T p.Q1261H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV67888334; called by muse, mutect2, varscan2
- GPR50 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV54441512; called by muse, mutect2, varscan2
- HRH1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV67955789; called by muse, mutect2, varscan2
- HUWE1 | c.10409C>T p.S3470L | Missense Mutation (SNP) | VAF 128/411 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as COSV53357747; called by muse, mutect2, varscan2
- IGHD | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.829); catalogued as COSV66655343; called by muse, mutect2
- JMJD6 | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57974390; called by muse, mutect2, varscan2
- KLHL9 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 5/126 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62921373; called by muse, mutect2
- KRTAP6-1 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 58/706 reads (8%) | PolyPhen benign (0.039); catalogued as rs369092171; called by muse, mutect2
- LCN12 | c.322C>G p.H108D | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.187); catalogued as COSV65422059; called by muse, mutect2, varscan2
- LINGO2 | c.1733A>G p.D578G | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as COSV58062410; called by muse, mutect2, varscan2
- MACF1 | c.10609C>T p.P3537S | Missense Mutation (SNP) | VAF 11/107 reads (10%) | catalogued as rs756324198, COSV57134579; called by muse, mutect2
- MAPK1IP1L | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV67106658; called by muse, mutect2, varscan2
- MRE11 | c.853G>T p.G285C | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60573843; called by muse, mutect2, varscan2
- NDUFS1 | c.1868T>G p.I623R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs201634181; called by muse, mutect2
- NMBR | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV57802577; called by muse, mutect2, varscan2
- ODF1 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 77/281 reads (27%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.14); catalogued as rs142535568; called by muse, mutect2, varscan2
- PJA2 | c.2002-1G>T p.X668_splice | Splice Site (SNP) | VAF 20/94 reads (21%) | catalogued as COSV63274031; called by muse, mutect2, varscan2
- PKIA | c.5C>G p.T2S | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as COSV61915713; called by muse, mutect2
- PTEN | c.1031del p.K344Sfs*8 | Frame Shift Del (DEL) | VAF 46/126 reads (37%) | catalogued as COSV64298040; called by mutect2, pindel, varscan2
- RSPO2 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 21/344 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs770159956, COSV52646166, COSV99409123; called by muse, mutect2
- SNTB2 | c.1450C>G p.P484A | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60348933, COSV60350826; called by muse, mutect2, varscan2
- SPAM1 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 74/299 reads (25%) | catalogued as COSV56146309, COSV99773390; called by muse, mutect2, varscan2
- TMC5 | c.2482C>T p.R828W (on ENST00000396229 / NM_001105248.1; = p.R582W on NM_024780.5) | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1313580380, COSV54903714; called by muse, mutect2, varscan2
- TRPA1 | c.2914T>A p.S972T | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.107); catalogued as COSV51569538; called by muse, mutect2
- TSSC4 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1314774857, COSV50169732; called by muse, mutect2
- ZBTB8OS | c.71A>G p.N24S | Missense Mutation (SNP) | VAF 98/294 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59386292; called by muse, mutect2, varscan2
- ZNF280B | c.1094T>G p.V365G | Missense Mutation (SNP) | VAF 96/300 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64529424; called by muse, mutect2, varscan2
- ALPK1 | c.322dup p.A108Gfs*79 | Frame Shift Ins (INS) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- ARID1A | c.1299del p.M434Cfs*185 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- ABCB4 | c.3786G>T p.T1262= (on ENST00000265723 / NM_018849.3; = p.T1255= on NM_000443.4) | Silent (SNP) | VAF 68/203 reads (33%) | catalogued as COSV55939409, COSV99709460; called by muse, mutect2, varscan2
- AMER2 | c.1485G>C p.R495= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV63439203; called by muse, mutect2, varscan2
- APP | c.933G>A p.V311= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV61002325; called by muse, mutect2, varscan2
- CRMP1 | c.993C>T p.S331= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs748941880, COSV61479032; called by muse, mutect2, varscan2
- LAMA3 | c.9867G>A p.T3289= (on ENST00000313654 / NM_198129.4; = p.T1680= on NM_000227.6) | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as rs763958106, COSV52539237; called by muse, mutect2, varscan2
- MAGEE1 | c.243G>A p.P81= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs782113948, COSV63911028; called by muse, mutect2, varscan2
- MMP12 | c.636G>A p.L212= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as rs868942536; called by muse, mutect2, varscan2
- NMBR | c.294G>A p.P98= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs370108261; called by muse, mutect2, varscan2
- PRMT8 | c.1014C>T p.T338= | Silent (SNP) | VAF 92/362 reads (25%) | catalogued as rs367772639; called by muse, mutect2, varscan2
- RBM46 | c.345A>G p.Q115= | Silent (SNP) | VAF 68/249 reads (27%) | catalogued as rs951534406, COSV55980813; called by muse, mutect2, varscan2
- TENM2 | c.1044G>A p.P348= (on ENST00000518659 / NM_001122679.2; = p.P157= on NM_001080428.3) | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs146310303; called by muse, mutect2, varscan2
- LINC02877 | n.407T>G | RNA (SNP) | VAF 65/180 reads (36%) | called by muse, mutect2, varscan2
